Gene-level copy-number profile of tumor specimen TCGA-44-4112-01A from TCGA case TCGA-44-4112, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.5 years (22,106 days).
Specimen TCGA-44-4112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b00d068f-9e5d-428c-82e9-666f2fb61df0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-4112-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e888bef8-352c-42db-9471-416823134823

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,789; copy number 4: 43,660; copy number 5: 92; copy number 6: 7,862; copy number 7: 302; copy number 8: 647; copy number 9: 191; copy number 11: 276.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-4112-01A-01D-A273-01): tumor purity 0.57, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 467 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,944,890–156,007,070, 237 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr1:172,659,103–180,909,166, 147 genes, copy number 9–11 (broad region; genes not listed).
- chr7:123,452,193–125,482,966, 34 genes, copy number 9: IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr7:138,002,324–138,118,305, 1 gene, copy number 9 (within-gene range 6–9): AKR1D1.
- chr7:138,060,056–139,423,457, 35 genes, copy number 9 (within-gene range 6–9): AC024082.2, RN7SKP223, RCC2P3, MIR4468, AC083867.2, Y_RNA, AC083867.1, AC008155.1, PTMAP10, IMPDH1P3, TRIM24, RPS3AP28, SVOPL, AC013429.2, AC013429.1, AC020983.1, UQCRFS1P2, ATP6V0A4, TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1.
- chr8:128,150,116–128,220,803, 2 genes, copy number 9: MIR1208, RN7SKP226.
- chr14:36,213,200–36,656,163, 11 genes, copy number 9 (within-gene range 4–9): AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
